Somatic mutation profile of tumor specimen 0DTNWC from CCDI case PBCJIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DTNWC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaa60cba-2114-4950-a0a1-65ca4772d43d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTNX8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7230ec-7d2c-4b41-b482-5439e6c6eb3f

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL645922.1 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 269/639 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754021968; called by muse, mutect2, varscan2
- ERGIC2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 251/604 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779908854; called by muse, mutect2, varscan2
- GLIPR1L2 | c.232A>C p.M78L | Missense Mutation (SNP) | VAF 177/409 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV57555307; called by muse, mutect2, varscan2
- CFHR2 | c.253+5G>A | Splice Region (SNP) | VAF 317/766 reads (41%) | called by muse, mutect2, varscan2
- NTRK3 | c.1735C>G p.L579V | Missense Mutation (SNP) | VAF 163/439 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- THOC2 | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 255/293 reads (87%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOP1B | c.6186T>A p.V2062= | Silent (SNP) | VAF 211/525 reads (40%) | called by muse, mutect2, varscan2
- OTOG | c.8322C>T p.S2774= | Silent (SNP) | VAF 191/435 reads (44%) | called by muse, mutect2, varscan2
- ZBTB43 | c.288C>T p.P96= | Silent (SNP) | VAF 301/753 reads (40%) | catalogued as rs770929392, COSV100991335, COSV100991491; called by muse, mutect2, varscan2
- CNOT2 | c.1391+35T>C | Intron (SNP) | VAF 107/249 reads (43%) | catalogued as rs779735859; called by muse, mutect2, varscan2
- HERC2 | c.13414+48G>A | Intron (SNP) | VAF 181/389 reads (47%) | catalogued as rs1370374611; called by muse, mutect2, varscan2
- ZNF843 | c.-83G>A | 5'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2
